Somatic mutation profile of tumor specimen TCGA-06-5856-01A (aliquot TCGA-06-5856-01A-01D-1696-08) from TCGA case TCGA-06-5856, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 58.1 years (21,232 days).
Specimen TCGA-06-5856-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bdd7855a-c371-41e6-a609-df0a2429ad94.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-06-5856-10A (Blood Derived Normal), aliquot TCGA-06-5856-10A-01D-1696-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/77386e4e-8e68-4074-b043-3f083522e990

The open-access MAF lists 56 somatic variants for this specimen: 44 protein-altering or splice-affecting, 10 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 44, Silent 10, Intron 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.866C>T p.A289V | Missense Mutation (SNP) | VAF 862/1570 reads (55%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as rs149840192, COSV51765841, COSV51768139; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ACTN1 | c.1925T>G p.I642S | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.337); catalogued as COSV51989271; called by muse, mutect2
- ADAMTS10 | c.2403G>T p.M801I | Missense Mutation (SNP) | VAF 33/100 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.034); catalogued as COSV54352743, COSV54353400; called by muse, mutect2, varscan2
- AHNAK | c.14998G>C p.V5000L | Missense Mutation (SNP) | VAF 7/126 reads (6%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.544); catalogued as COSV57206281; called by muse, mutect2
- ALDOA | c.763C>T p.R255C (on ENST00000642816 / NM_001243177.4; = p.R201C on NM_184041.5) | Missense Mutation (SNP) | VAF 11/123 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.017); catalogued as rs372394541, COSV57633972; called by muse, mutect2
- BCL11A | c.973C>G p.P325A (on ENST00000335712 / NM_001365609.1; = p.P359A on NM_018014.4) | Missense Mutation (SNP) | VAF 23/120 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.071); catalogued as rs1460781043, COSV59625789; called by muse, mutect2, varscan2
- BCL9 | c.2132T>G p.M711R | Missense Mutation (SNP) | VAF 5/92 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.367); catalogued as COSV52341970; called by muse, mutect2
- C1orf198 | c.599G>A p.G200E | Missense Mutation (SNP) | VAF 66/182 reads (36%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.466); catalogued as COSV64174757; called by muse, mutect2, varscan2
- C9orf131 | c.2260T>C p.C754R | Missense Mutation (SNP) | VAF 51/135 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV56609964; called by muse, mutect2, varscan2
- CBX8 | c.329C>T p.S110L | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.397); catalogued as rs759741194, CM142320, COSV53935720; called by muse, mutect2, varscan2
- CC2D1A | c.1025C>A p.P342H | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); catalogued as COSV58781728; called by muse, mutect2, varscan2
- CDC37 | c.251T>A p.L84Q | Missense Mutation (SNP) | VAF 72/177 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.452); catalogued as COSV55767575; called by muse, mutect2, varscan2
- CDHR1 | c.643G>T p.G215C | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60560349; called by muse, mutect2, varscan2
- CNOT2 | c.906G>C p.L302F | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.297); catalogued as COSV57501538; called by muse, varscan2
- CNOT2 | c.993G>C p.Q331H | Missense Mutation (SNP) | VAF 29/146 reads (20%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.783); catalogued as COSV57501550; called by muse, mutect2, varscan2
- CRACR2A | c.500T>C p.L167P | Missense Mutation (SNP) | VAF 28/788 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV52911021; called by muse, mutect2
- DUS3L | c.370T>G p.C124G | Missense Mutation (SNP) | VAF 7/81 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57831347; called by muse, mutect2
- FBP1 | c.397G>A p.V133I | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs368583779; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FNIP2 | c.2477C>G p.A826G | Missense Mutation (SNP) | VAF 71/183 reads (39%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV52437503; called by muse, mutect2, varscan2
- FSCB | c.1624G>T p.A542S | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.037); catalogued as rs765495778, COSV61217054; called by muse, mutect2, varscan2
- GNG5 | c.105G>T p.L35F | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.309); catalogued as COSV55361559; called by muse, mutect2, varscan2
- GPR45 | c.845C>T p.P282L | Missense Mutation (SNP) | VAF 92/281 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51523096; called by muse, mutect2, varscan2
- HCK | c.217A>T p.I73F | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as COSV52940978; called by muse, mutect2, varscan2
- IFNG | c.143A>G p.N48S | Missense Mutation (SNP) | VAF 437/568 reads (77%) | SIFT tolerated (0.06); PolyPhen benign (0.022); catalogued as COSV57490835; called by muse, mutect2, varscan2
- IL1RAPL2 | c.2045C>T p.T682I | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.585); catalogued as COSV61146320; called by muse, mutect2
- KIAA2026 | c.3232C>A p.L1078I | Missense Mutation (SNP) | VAF 73/113 reads (65%) | SIFT tolerated (0.07); PolyPhen benign (0.11); catalogued as rs764999447, COSV67353819; called by muse, mutect2, varscan2
- KPRP | c.457T>G p.Y153D | Missense Mutation (SNP) | VAF 86/156 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV64221187; called by muse, mutect2, varscan2
- L1CAM | c.32T>G p.L11R | Missense Mutation (SNP) | VAF 24/33 reads (73%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.947); catalogued as COSV62808000; called by muse, mutect2, varscan2
- LZTR1 | c.1772T>G p.L591R | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV53145816; called by muse, mutect2, varscan2
- MAP4K3 | c.432A>C p.L144F | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55711008; called by muse, mutect2, varscan2
- MED13 | c.2871G>T p.M957I | Missense Mutation (SNP) | VAF 57/120 reads (48%) | SIFT tolerated (0.39); PolyPhen benign (0.164); catalogued as COSV67262380; called by muse, mutect2, varscan2
- MUC7 | c.104A>G p.H35R | Missense Mutation (SNP) | VAF 22/116 reads (19%) | SIFT tolerated (0.37); PolyPhen benign (0.174); catalogued as rs768817716, COSV59217417; called by muse, mutect2, varscan2
- MYO1G | c.110G>A p.R37H | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.913); catalogued as rs763720788, COSV51853574; called by muse, mutect2, varscan2
- NDUFA9 | c.619T>C p.F207L | Missense Mutation (SNP) | VAF 18/188 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as rs1182468208, COSV56928087; called by muse, mutect2
- NEK1 | c.3047G>T p.R1016L | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as rs764463497, COSV71454923; called by muse, mutect2, varscan2
- NPR1 | c.1526G>A p.R509Q | Missense Mutation (SNP) | VAF 33/129 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.327); catalogued as rs1434161100, COSV64117372; called by muse, mutect2, varscan2
- OR2M3 | c.356C>A p.A119D | Missense Mutation (SNP) | VAF 8/178 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.768); catalogued as COSV71758926, COSV71759235; called by muse, mutect2
- POLI | c.2176G>A p.A726T | Missense Mutation (SNP) | VAF 30/50 reads (60%) | SIFT tolerated (0.08); PolyPhen benign (0.255); catalogued as COSV54188144; called by muse, mutect2, varscan2
- PPIL2 | c.1004C>A p.P335H | Missense Mutation (SNP) | VAF 43/232 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV58605178; called by muse, mutect2, varscan2
- PRRT3 | c.1219C>T p.P407S | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV55976585; called by muse, mutect2
- SCN3B | c.406A>G p.K136E | Missense Mutation (SNP) | VAF 47/72 reads (65%) | SIFT tolerated (0.93); PolyPhen benign (0.003); catalogued as COSV54798510; called by muse, mutect2, varscan2
- SPAG17 | c.4916T>A p.V1639D | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs548598350, COSV60454707; called by muse, mutect2, varscan2
- ZC3HAV1L | c.434T>C p.L145P | Missense Mutation (SNP) | VAF 36/98 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV51964176; called by muse, mutect2, varscan2
- ZFX | c.2081A>C p.H694P | Missense Mutation (SNP) | VAF 107/120 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58446768; called by muse, mutect2, varscan2
- ACOT4 | c.510C>A p.L170= | Silent (SNP) | VAF 36/123 reads (29%) | catalogued as COSV58335442, COSV58336267; called by muse, mutect2, varscan2
- C2orf16 | c.384G>A p.Q128= | Silent (SNP) | VAF 30/87 reads (34%) | catalogued as COSV68645508; called by muse, mutect2, varscan2
- CDC37L1 | c.120C>G p.G40= | Silent (SNP) | VAF 27/122 reads (22%) | catalogued as COSV67865779; called by muse, mutect2, varscan2
- H2AC1 | c.177C>A p.L59= | Silent (SNP) | VAF 39/51 reads (76%) | catalogued as COSV51236866; called by muse, mutect2, varscan2
- MAPKBP1 | c.1197C>T p.P399= (on ENST00000456763 / NM_001128608.2; = p.P393= on NM_014994.3) | Silent (SNP) | VAF 29/64 reads (45%) | catalogued as rs936137674, COSV52959019, COSV52965086; called by muse, varscan2
- MTMR2 | c.1146C>T p.N382= | Silent (SNP) | VAF 11/50 reads (22%) | catalogued as COSV60578847; called by muse, mutect2, varscan2
- MYO10 | c.6060C>T p.L2020= | Silent (SNP) | VAF 105/210 reads (50%) | catalogued as rs750415980, COSV57018182; called by muse, mutect2, varscan2
- PRAMEF19 | c.654G>A p.P218= | Silent (SNP) | VAF 77/345 reads (22%) | catalogued as rs1318111197; called by muse, mutect2, varscan2
- R3HDML | c.558C>T p.T186= | Silent (SNP) | VAF 18/286 reads (6%) | catalogued as COSV53835419, COSV99407276; called by muse, mutect2
- SLC9A3 | c.1494C>T p.I498= | Silent (SNP) | VAF 41/383 reads (11%) | catalogued as rs200474984; called by muse, mutect2, varscan2
- KNSTRN | c.-2G>C | 5'UTR (SNP) | VAF 3/24 reads (13%) | catalogued as COSV99991749; called by muse, mutect2
- OBSCN | c.11659+4284C>A | Intron (SNP) | VAF 11/70 reads (16%) | catalogued as COSV99472851; called by muse, mutect2, varscan2
